CCDI case PBCGGS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8c8ca284-de7a-4446-b2d0-b862cfb162e4

Demographics
Sex at birth: female.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.2 years (3,350 days).

Biospecimens (3 samples)
- Sample 0DRKKB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRKKL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRKKU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
